Somatic mutation profile of tumor specimen MP2PRT-PATKUX-TMP1-A (aliquot MP2PRT-PATKUX-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATKUX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,179 days).
Specimen MP2PRT-PATKUX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f623c12-b46e-4779-ab2d-30772ff0b428.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKUX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKUX-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b23694b-6eac-4ad5-aa10-102fe826b65f

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 97/377 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGAP2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 190/592 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); catalogued as rs1429127085; called by muse, mutect2, varscan2
- AGRN | c.4517C>T p.A1506V | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs373657385; ClinVar: uncertain significance; called by muse, mutect2
- CHRNA3 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 29/495 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs199640841, CM0910890; called by muse, mutect2
- DOCK1 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 113/496 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs373968953; called by muse, mutect2, varscan2
- FLRT2 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 130/427 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58139254; called by muse, mutect2, varscan2
- GAL3ST3 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 32/790 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs770632222; called by muse, mutect2
- ITGB5 | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773181407, COSV56146615; called by muse, mutect2, varscan2
- LAMB1 | c.4966G>A p.E1656K | Missense Mutation (SNP) | VAF 38/764 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.196); catalogued as rs1380170088; called by muse, mutect2
- LYZL2 | c.209G>A p.R70H (on ENST00000375318; = p.R24H on NM_183058.3) | Missense Mutation (SNP) | VAF 151/995 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs375255325, COSV100940618; called by muse, mutect2, varscan2
- MISP | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 194/603 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as rs374036064; called by muse, mutect2
- NIPBL | c.5272C>T p.R1758* | Nonsense Mutation (SNP) | VAF 123/380 reads (32%) | catalogued as CM042515, COSV56948411, COSV56958347; called by muse, mutect2, varscan2
- CCDC158 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQSEC1 | c.2441T>C p.L814P | Missense Mutation (SNP) | VAF 132/344 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- NID1 | c.2740G>A p.G914R | Missense Mutation (SNP) | VAF 170/443 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CSMD1 | c.5808C>T p.D1936= (on ENST00000520002; = p.D1935= on NM_033225.6) | Silent (SNP) | VAF 40/738 reads (5%) | catalogued as rs559577751, COSV100156099; called by muse, mutect2
- RYR2 | c.606C>T p.H202= | Silent (SNP) | VAF 124/405 reads (31%) | catalogued as rs1438256315, COSV63691206; called by muse, mutect2, varscan2
- SH3BP4 | c.1020C>T p.H340= | Silent (SNP) | VAF 171/526 reads (33%) | catalogued as rs779262308; called by muse, mutect2, varscan2
